Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A13X, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A13X-01A (Primary Tumor).

[page 1 of 4]
Clinical Diagnosis & History:

Right thyroid nodule FNA showed papillary thyroid cancer.

HPV & Discrepancy		/

Specimens Submitted:

- 1: SP: Delphian lymph node (fs)
- 2: SP: Total thyroid; Thyroidectomy

DIAGNOSIS:

1. SP: Lymph node, Delphian; Excision (fs):
-One benign lymph node (0/1)
2. SP: Total thyroid; Thyroidectomy:
Tumor Type:
Papillary carcinoma, follicular variant

Histologic Grade:
Well differentiated

Mitotic Activity:
Not identified

Tumor Necrosis:
Not identified

Tumor Location:
Right lobe

Tumor Size:
Greatest diameter is 6.5 cm.

Tumor Encapsulation:
Completely surrounded

Capsular Invasion:
Focal invasion

Blood Vessel Invasion:
Not identified

Extrathyroid Extension:
Not identified

Surgical Margins:
Free of tumor

Tumor Multicentricity:
Not identified

ICD-0-3

Carcinoma, Pap.illary w/ follicular variant

8340/3

Site: thyroid, nos C73.9

lw
11/16/10

[page 2 of 4]
Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

INPATIENT

Clinical Diagnosis & History:

Right thyroid nodule FNA showed papillary thyroid cancer.

Specimens Submitted:

- 1: SP: Delphian lymph node (fs)
2: SP: Total thyroid; Thyroidectomy

DIAGNOSIS:

1. SP: Lymph node, Delphian; Excision (fs):
-One benign lymph node (0/1)
2. SP: Total thyroid; Thyroidectomy:
Tumor Type:
Papillary carcinoma, follicular variant

Histologic Grade:
Well differentiated

Mitotic Activity:
Not identified

Tumor Necrosis:
Not identified

Tumor Location:
Right lobe

Tumor Size:
Greatest diameter is 6.5 cm.

Tumor Encapsulation:
Completely surrounded

Capsular Invasion:
Focal invasion

Blood Vessel Invasion:
Not identified

Extrathyroid Extension:
Not identified

Surgical Margins:
Free of tumor

Tumor Multicentricity:
Not identified

[page 3 of 4]
Non-Neoplastic Thyroid:
Exhibits nodular hyperplasia
mild
Parathyroid Glands:
Not identified

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh for frozen section consultation, labeled "Delphian lymph node" and consists of one tan lymph node measuring 0.6 cm in greatest dimension. Entirely submitted for frozen section.

Summary of sections:
FSC - frozen section control

2) The specimen is received fresh, labeled "total thyroid stitch marks right lobe" and consists of a thyroid weighing 42.5 G. The right lobe measures 7 x 6 x 4 cm, the left lobe measures 3 x 1.5 x 1.0 cm and the isthmus measures 2.0 x 0.5 x 0.3 cm. The external surface is covered by a thin fibrous capsula. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a large tumor in the right lobe measuring 6.5 x 5.5 x 4.0 cm with fleshy, tan brown cut surface. Sections through the remaining tissue reveal unremarkable thyroid parenchyma. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen are submitted for TPS, and a photograph has been taken.

Summary of sections:
N - nodule
RL - right lobe
LL - left lobe
IS - isthmus

Summary of Sections:

Part 1: SP: Delphian lymph node (fs)

Block	Sect. Site	PCs
1	fsc	1

Part 2: SP: Total thyroid; Thyroidectomy

Block	Sect. Site	PCs
1	is	1
1	ll	1
8	n	8
1	rl	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: DELPHIAN LYMPH NODE (FS): BENIGN LYMPH NODE
PERMANENT DIAGNOSIS: SAME

[page 4 of 4]
last page of

Source: NCI Genomic Data Commons file b53db840-4b13-4a6d-afa8-7d968ae9fd2d (TCGA-DJ-A13X.FA8ABF27-AF99-41FD-85EB-49F2975C0E1B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).